Somatic mutation profile of tumor specimen 0DITT5 from CCDI case PBBVUD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.2 years (3,345 days).
Specimen 0DITT5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5990716b-f207-406b-adec-e322452b4167.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DITSC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/826aaeb3-9fea-4b94-a039-23338b9c17e8

The open-access MAF lists 42 somatic variants for this specimen: 31 protein-altering or splice-affecting, 8 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 8, Intron 1, Frame Shift Del 1, Nonsense Mutation 1, 5'UTR 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 301/1127 reads (27%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, varscan2
- TP53 | c.747G>T p.R249S | Missense Mutation (SNP) | VAF 391/527 reads (74%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs28934571, COSV52661594, COSV52668882, COSV52827572; ClinVar: pathogenic / likely pathogenic / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- ACAT1 | c.1003A>G p.M335V | Missense Mutation (SNP) | VAF 263/501 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs369440498; called by muse, mutect2, varscan2
- ALOX5AP | c.418G>A p.G140R | Missense Mutation (SNP) | VAF 489/1178 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as rs142957781; called by muse, mutect2, varscan2
- ATRX | c.6563G>C p.R2188P | Missense Mutation (SNP) | VAF 268/729 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64879508, COSV64879971; called by muse, mutect2, varscan2
- BMP4 | c.1159G>A p.D387N | Missense Mutation (SNP) | VAF 648/923 reads (70%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV55416113; called by muse, mutect2, varscan2
- EPAS1 | c.2482G>A p.G828R | Missense Mutation (SNP) | VAF 427/1078 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as rs749690854; called by muse, mutect2, varscan2
- FOXA2 | c.287C>T p.A96V (on ENST00000377115 / NM_153675.3; = p.A102V on NM_021784.5) | Missense Mutation (SNP) | VAF 77/612 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV65795838; called by muse, mutect2, varscan2
- HERC6 | c.3047C>T p.S1016L | Missense Mutation (SNP) | VAF 176/1139 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.809); catalogued as rs1391776203; called by muse, mutect2, varscan2
- NWD2 | c.3605G>A p.S1202N | Missense Mutation (SNP) | VAF 227/1112 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs764557018; called by muse, mutect2, varscan2
- PCYT1A | c.398A>G p.Y133C | Missense Mutation (SNP) | VAF 111/987 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767604749; called by muse, mutect2, varscan2
- RARS2 | c.938T>C p.V313A | Missense Mutation (SNP) | VAF 93/1484 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as COSV65760836; called by muse, mutect2
- RNF43 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 275/982 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs758286312, COSV101348619, COSV68457536; called by muse, mutect2, varscan2
- SH3BGR | c.218C>A p.S73Y | Missense Mutation (SNP) | VAF 444/1102 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV61323508; called by muse, mutect2, varscan2
- TDRD10 | c.1027A>T p.T343S | Missense Mutation (SNP) | VAF 158/1608 reads (10%) | SIFT tolerated, low confidence (0.32); PolyPhen possibly damaging (0.533); catalogued as COSV99427556; called by muse, mutect2
- TYR | c.1246G>T p.A416S | Missense Mutation (SNP) | VAF 219/639 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as CM041484; called by mutect2, varscan2
- WDR49 | c.2040A>C p.K680N (on ENST00000308378 / NM_001366158.1; = p.K1021N on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 124/943 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as COSV52985200; called by muse, mutect2, varscan2
- AKNAD1 | c.896T>A p.V299E | Missense Mutation (SNP) | VAF 483/1234 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- C21orf62 | c.246C>G p.I82M | Missense Mutation (SNP) | VAF 81/1099 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); called by muse, mutect2
- CHUK | c.187C>G p.Q63E | Missense Mutation (SNP) | VAF 373/540 reads (69%) | SIFT tolerated (0.08); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- CUBN | c.9957G>T p.K3319N | Missense Mutation (SNP) | VAF 291/1080 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.763); called by mutect2, varscan2
- CUL4B | c.2096C>A p.P699Q | Missense Mutation (SNP) | VAF 147/900 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- KIF3C | c.1493A>G p.E498G | Missense Mutation (SNP) | VAF 131/1600 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2
- MAOA | c.1263G>A p.R421= | Splice Region (SNP) | VAF 354/614 reads (58%) | called by muse, mutect2, varscan2
- MRTFB | c.1843G>C p.E615Q | Missense Mutation (SNP) | VAF 214/601 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MYO1G | c.1892T>C p.V631A | Missense Mutation (SNP) | VAF 34/1139 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- RBBP8 | c.859G>T p.E287* | Nonsense Mutation (SNP) | VAF 459/1140 reads (40%) | called by muse, mutect2, varscan2
- SIPA1L1 | c.2123del p.N708Mfs*4 | Frame Shift Del (DEL) | VAF 266/362 reads (73%) | called by mutect2, varscan2
- TMPPE | c.644T>C p.I215T | Missense Mutation (SNP) | VAF 319/702 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TUBB2B | c.128A>G p.Q43R | Missense Mutation (SNP) | VAF 435/1110 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- UGT2A1 | c.782A>G p.D261G | Missense Mutation (SNP) | VAF 267/701 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASPRV1 | c.759C>A p.I253= | Silent (SNP) | VAF 367/990 reads (37%) | called by muse, mutect2, varscan2
- CNTNAP1 | c.1113C>T p.F371= | Silent (SNP) | VAF 208/2402 reads (9%) | catalogued as rs1254716843, COSV52847801; called by muse, mutect2
- DYRK1A | c.1602G>A p.Q534= | Silent (SNP) | VAF 109/1065 reads (10%) | catalogued as rs1555991440; ClinVar: likely benign; called by muse, mutect2, varscan2
- FREM2 | c.3075A>C p.L1025= | Silent (SNP) | VAF 212/514 reads (41%) | called by muse, mutect2, varscan2
- LOX | c.1152C>T p.Y384= | Silent (SNP) | VAF 31/1147 reads (3%) | called by muse, mutect2
- MOB3C | c.393C>T p.D131= | Silent (SNP) | VAF 481/1201 reads (40%) | catalogued as rs372911972; called by muse, mutect2, varscan2
- MUC5B | c.14118C>T p.T4706= | Silent (SNP) | VAF 48/1713 reads (3%) | called by muse, mutect2
- TTLL10 | c.951C>A p.S317= (on ENST00000379289 / NM_001130045.2; = p.S244= on NM_153254.3) | Silent (SNP) | VAF 368/906 reads (41%) | called by muse, mutect2, varscan2
- IMPACT | c.-67C>A | 5'UTR (SNP) | VAF 84/194 reads (43%) | called by muse, mutect2, varscan2
- SLC17A4 | c.1268+65T>A | Intron (SNP) | VAF 106/731 reads (15%) | called by muse, mutect2, varscan2
- ZNF550 | c.*585T>G | 3'UTR (SNP) | VAF 118/495 reads (24%) | called by muse, mutect2, varscan2
